Gene-level copy-number profile of specimen HCM-CSHL-0432-C20-85A from HCMI case HCM-CSHL-0432-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-CSHL-0432-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 970ce6ab-34f3-4018-a38e-89ecd6608d54.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0432-C20-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/69a0e8f5-a222-429e-85fe-350f10e78b31

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 458; copy number 1: 3,431; copy number 2: 48,757; copy number 3: 6,107; copy number 4: 38; copy number 5: 118; copy number 6: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 121 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:198,493,242–198,772,356, 1 gene, copy number 5 (within-gene range 2–5): AC019330.1.
- chr3:68,004,247–75,625,188, 104 genes, copy number 5 (broad region; genes not listed).
- chr5:50,396,192–50,846,519, 5 genes, copy number 5: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8.
- chr7:20,328,299–20,415,754, 3 genes, copy number 6: AC004130.2, ITGB8, AC004130.1.
- chr8:127,289,817–127,482,139, 4 genes, copy number 5: CASC8, AC018714.1, POU5F1B, CCAT2.
- chr13:26,905,362–27,017,909, 4 genes, copy number 5: FGFR1OP2P1, AL160035.1, RPS21P8, RPS20P32.

Autosomal genes at a single copy (total copy number 1): 3,431. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
